Surgical pathology report (de-identified scan), TCGA case TCGA-UB-A7ME, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UCSF, specimen TCGA-UB-A7ME-01A (Primary Tumor).

[page 1 of 4]
Results

Surgical Pathology

(enter 1 per line): liver segment 7 tumor (Order

Result Information

Status (Last updated Date/Time)

Accession #

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED]
DOB: [REDACTED]
Sex: Male
Soc. Sec. #: [REDACTED]
Accession #: [REDACTED]
Visit #: [REDACTED]
Service
Receive
Locatio
Client:
Physici

ICD-O-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
QJ 9/26/13

FINAL PATHOLOGIC DIAGNOSIS

Liver, segment 7, partial hepatectomy:

1. Moderately differentiated hepatocellular carcinoma; see comment.
2. Cavernous hemangioma.
3. Chronic hepatitis B; see comment.
4. Mild steatosis.

COMMENT:

Liver Tumor Synoptic Comment

- Tumor type: Hepatocellular carcinoma, macrotrabecular and pseudoglandular patterns.
- Histologic grade: Moderately differentiated.
- Tumor size (maximum diameter of largest lesion): 3.5 cm.
- Tumor necrosis: <30%.
- Multifocality: Absent.
- Estimated total tumor diameter of all HCC foci: 3.5 cm.
- Vascular invasion: None.
- Hepatic capsule: No tumor in capsule.
- Local extension of tumor: Confined to liver.
- Hepatic surgical margins: Negative; tumor is 1.2 cm from resection margin (slide A2).
- Non-neoplastic liver: Hepatitis B (see below); mild steatosis.
- Lymph node status: None present.

[page 2 of 4]
[REDACTED]

- AJCC Stage: pT1NX.

In addition to the hepatocellular carcinoma, there is also a 2 cm cavernous hemangioma. Sections of the hepatic parenchyma away from the tumor show intact portal tracts with minimal to mild, predominately lymphocytic portal inflammation. Scattered ground-glass hepatocytes are identified (highlighted on a trichrome stain) as well as lobular inflammation with a few necrotic cells. Mild steatosis is also present.

A trichrome stain shows periportal fibrosis with focally thin septa. Overall, since these changes are adjacent to a mass lesion the chronic hepatitis B is scored as grade 1 activity and stage 1 fibrosis.

Chronic Hepatitis Synoptic Comment:

- Type of hepatitis: Hepatitis B virus.
- Necroinflammatory activity (grade 0-4): 1 (see above).
- Fibrosis (stage 0-4): 1 (see above).
- Number of portal zones, >45.
- Steatosis, scale 0-3 with 0 <5%: 1

Specimen(s) Received
A: Liver segment 7 tumor

Clinical History

Relevant History: hep B, hcc

The patient is a -year-old man with a history of hepatitis B and HCC. According to an MRI performed on showed three hemangiomas and a solitary segment 7 lesion (2.6 cm), compatible with hepatocellular carcinoma; there was no evidence of cirrhosis. The serum AFP was 1388.8 on Additional history includes cholecystectomy. The patient now undergoes resection of hepatic segment 7 and a portion of segment 8.

Gross Description

The case is received fresh in one part, labeled with the patient's name, medical record number and "liver segment 7 tumor," and consists of an unoriented wedge of liver parenchyma (122 g; 10 x 7.5 x 3.6 cm).

Two well-circumscribed, non-encapsulated masses are identified. Mass #1 (3.5 x 2.3 x 2.1 cm) is firm, multinodular, homogenous and white-tan, and abuts the hepatic capsule. Mass #1 is located within 1.1 cm of the resection margin (inked blue). Mass #2 (2 x 2 by 2 cm) is spongy, soft, dark red-purple, and abuts the hepatic capsule. Mass #2 approaches the resection margin to within 0.2 cm. Mass #2 is located 1.5 cm from mass #1. The surrounding uninvolved liver parenchyma is soft, dark rust-tan and homogenous. The capsule is predominately smooth, dark red-purple and glistening, with an irregular, rough area (less than 40%) at one end. The specimen was previously partially sectioned prior to receipt in Pathology, as there are multiple linear slices into the specimen and into mass #1. A portion of the liver parenchyma including part of Mass #1 and part of the nearest resection margins is absent. Representative sections are submitted in the following cassettes:
A1, A2: Mass #1 with closest approach to resection margin.

[REDACTED]

[page 3 of 4]
[REDACTED]

A3: Mass #1 with overlying capsule.
A4: Mass #2 with overlying capsule and closest approach to
resection margin.
A5: Liver parenchyma.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

Electronically signed

Authorizing

Name: _____

Phone: _____

Signed by

Signed _____

Phone _____

Pager _____

Result History

SURGICAL PATHOLOGY

Surgical Pathology

(enter 1 per line): liver segment 7 tumor (

This is NOT a Requisition. Requisition hyperlink below.

Surgical Pathology

(enter 1 per line): liver segment 7 tumor

Pathology and Cytology

Authorizi

Departme

Order Information

Order Date/Time

Release Date/Time

Start Date/Time

End Date/Time

Release Information

Released On

Released By

Order Details

Frequency
Once

Duration
1 occurrence

Priority
Routine

Order Class
Unit Collect

Order Questions

Question

Answer

Comment

[REDACTED]

[page 4 of 4]
Specimen (enter 1 per line) liver segment 7
tumor
hep B, hcc

Lab Collection and Receipt Information

Collect Date Collect Time Collected By Lab Receipt Date Lab Receipt Time

Collection Information

Resulting Agency

Order Provider Info

	Office phone	Pager/beeper	E-mail
Ordering User			--
Authorizing Provider			--
Billing Provider			--

Electronically Signed By:

Electronically Authorized By Electronically Ordered By

Acknowledgement Info

For	At	Acknowledged By	Acknowledged On
-----	----	-----------------	-----------------

Order Status for: SURGICAL PATHOLOGY

Parent Status: Completed

Child Orders

(This order does not yet have any children)

Order Requisition

Surgical Pathology (enter 1 per line): liver segment 7 tumor

mpPA Discrepancy		✓

Source: NCI Genomic Data Commons file 9a26145a-871c-49ea-bc83-1b1070a04f4c (TCGA-UB-A7ME.AAC76123-7B45-4C65-A90D-EEE823A0F84B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).